Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5JG, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5JG-01A (Primary Tumor).

[page 1 of 5]
Requesting Doctor's Information:

HISTOPATHOLOGY FOR REVIEW

At the request of the treating physicians and surgeons immunohistochemistry for multiple markers was performed on the adrenal cortical carcinoma removed in
The Weiss score of the tumour is 9. The mitotic rate is up to
100 per 50 HPF.

The immunohistochemical results are as follows:

IGF2: Negative (score 0).

Glucocorticoid Receptor: Focal weak staining (score 2+).

Ki-67 proliferative index: 30%

ACADVL: Positive

REPORTING PATHOLOGIST:

(Electronic Signature)

ICD-8-3

Carcinoma, adrenal cortical 8370/3

Site: ① Adrenal Gland, cortex 174.2

4W 1/30/13

P
A
T
H
O
L
O
G
Y

A
N
A
T
O
M
I
C
A
L

P
A
T
H
O
L
O

[page 2 of 5]
Specimen(s) Received

(1) Tumour left (2) Tumour near left renal artery (3) Tumour near left coeliac artery (4) Adrenal gland and left kidney (5) Lymph node of greater curvature of stomach (6) Lymph node near splenic vein (7) Retro aortic lymph node (8) Aorto-caval node in front of left renal vein (9) Tumour in thoracic duct (10) Left radical neck dissection (11) Peritoneal fluid

Clinical History

Tumour in thoracic duct suggestive of adrenocortical cancer; peritoneal fluid; Tumour left Tumour near left renal artery; Tumour near coeliac artery; Left adrenal gland and left kidney; Lymph node near great curvature of stomach; Lymph node near splenic vein; Retro aortic lymph nodes; Aorto-caval lymph nodes in front of left renal vein; Left cervical zone IV/VI lymph nodes. Silk suture on thoracic duct.

Macroscopic Description

- (1) The specimen consists of a lobulated grey nodule 15 x 8 x 5mm.
- (2) The specimen consists of two grey nodules 6 x 5 x 3mm and 6 x 3 x 2mm
- (3) The specimen consists of a grey nodule 12 x 12 x 12mm.
- (4) The specimen consists of a left kidney, left adrenal gland, adjacent lymph nodes and surrounding fatty tissue, together measuring 240 x 160 x 100mm (see photograph 1).
The kidney is 110 x 60 x 60mm and shows no significant abnormality. (Continued page 2)

Referred by:

Page 1 of 4

[page 3 of 5]
For all enquiries
please quote:

The adrenal gland is 65 x 65 x 40mm and expanded by a lobulated grey solid tumour (see photographs 2 & 3). Numerous replaced lymph nodes up to 40mm in diameter are present. The renal vein shows no significant abnormality (A: Kidney B-D: Adrenal tumour; E&F: Lymph nodes).

(5) The specimen consists of a lymph node 15 x 10 x 10mm and adjacent fatty tissue. (A-B: RST).

(6) The specimen consists of a lymph node 20 x 20 x 20mm and adjacent fatty tissue. (A-B: RST).

(7) The specimen consists of fatty tissue 70 x 30 x 20mm containing lymph nodes up to 20mm in diameter. (A-B: RST).

(8) The specimen consists of fatty tissue 30 x 18 x 6mm containing lymph nodes 3-5mm in diameter.

(9) The specimen consists of a piece of grey tissue 3 x 2 x 2mm. All embedded.

(10) The specimen consists of a triangular piece of fatty tissue 60 x 20 x 20mm containing lymph nodes up to 30mm in diameter with a silk suture reaching one end of a portion of thoracic duct 15mm long (see photograph 4). (A: Thoracic duct; B: Lymph node adjacent to thoracic; C&D: Other lymph nodes.)

[page 4 of 5]
For all enquiries
please quote

Microscopic Description

(1) - (3) Sections show nodules of metastatic adrenal cortical carcinoma arranged in sheets and islands.
(4) Sections of the adrenal gland show adrenal cortical carcinoma (see photograph 5) replacing the adrenal gland, with multiple nodules of metastatic adrenal cortical carcinoma close to the hilum of the kidney where the tumour abuts the resection margin. The tumour shows positive staining for Inhibin A and Melan A, with negative staining for Cytokeratin, EMA and chromogranin. Prominent lymphatic invasion is present.
The kidney shows no evidence of malignancy.

Referred by:

Page 3 of 4

[page 5 of 5]
For all enquiries
please quote

- (5) - (7) Sections show metastatic adrenal cortical carcinoma replacing lymph nodes.
(8) Sections of the lymph nodes show no evidence of malignancy.
(9) Sections show thoracic duct wall, with no evidence of malignancy.
(10) Sections of the lymph nodes show metastatic adrenal cortical carcinoma. The thoracic duct segment shows no evidence of malignancy.

Final Summary

TUMOUR, LEFT CRUS	:	METASTATIC ADRENAL CORTICAL CARCINOMA
TUMOUR, NEAR LEFT RENAL ARTERY	:	METASTATIC ADRENAL CORTICAL CARCINOMA
TUMOUR, LEFT COELIAC ARTERY	:	METASTATIC ADRENAL CORTICAL CARCINOMA
LEFT ADRENAL GLAND	:	ADRENAL CORTICAL CARCINOMA
LEFT KIDNEY	:	NO EVIDENCE OF MALIGNANCY
LYMPH NODES, GREATER CURVATURE OF STOMACH	:	METASTATIC ADRENAL CORTICAL CARCINOMA
LYMPH NODE NEAR SPLENIC VEIN	:	METASTATIC ADRENAL CORTICAL CARCINOMA
RETRO AORTIC LYMPH NODE	:	METASTATIC ADRENAL CORTICAL CARCINOMA
AORTO CAVAL NODE IN FRONT OF LEFT RENAL VEIN	:	NO EVIDENCE OF MALIGNANCY
TUMOUR, IN THORACIC DUCT	:	NO EVIDENCE OF MALIGNANCY
LEFT RADICAL NECK DISSECTION	:	METASTATIC CORTICAL ADRENAL CARCINOMA

Criteria	W 1/4/13	Yes	No

Reported By:

Referred by: Or

Source: NCI Genomic Data Commons file 202cb605-962d-4827-aa11-18064c732fb2 (TCGA-OR-A5JG.15F6D8D6-878A-410F-8289-D3CEAB7E5D21.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).